Somatic mutation profile of tumor specimen C3N-01899-02 (aliquot CPT0162450036) from CPTAC case C3N-01899, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.8 years (23,307 days).
Specimen C3N-01899-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6546c5af-77c1-4df7-93df-00ce90cf14c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01899-31 (Blood Derived Normal), aliquot CPT0162500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b875eed1-31c4-4708-aad4-f55418dbe361

The open-access MAF lists 44 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Intron 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 33/276 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDH6 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs868021169, COSV54063594; called by muse, mutect2, varscan2
- COL3A1 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 30/306 reads (10%) | catalogued as rs572097661, COSV58595344; called by muse, mutect2, varscan2
- DNAH11 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs769397639, COSV60959013; called by muse, mutect2, varscan2
- DNAH17 | c.7115G>A p.R2372Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs780980042, COSV101102805; called by muse, mutect2
- HELZ2 | c.3571G>A p.V1191M (on ENST00000467148 / NM_001037335.2; = p.V622M on NM_033405.3) | Missense Mutation (SNP) | VAF 54/497 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs961369377; called by muse, mutect2
- JAG2 | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 17/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1452922654; called by muse, mutect2
- MUC2 | c.3016C>T p.R1006W | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs370583278; called by muse, mutect2, varscan2
- OR2AJ1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.493); catalogued as rs1368156458, COSV59089281; called by muse, mutect2
- PREX1 | c.2707C>T p.R903W | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs759318978; called by muse, mutect2, varscan2
- PRKCSH | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV52950434; called by muse, mutect2
- PRRC2B | c.3824G>A p.R1275H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs773972580; called by muse, mutect2
- SOX30 | c.1534C>A p.R512S | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs571563119, COSV53936569; called by muse, mutect2
- TNXB | c.7090G>A p.V2364I (on ENST00000647633; = p.V2117I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as rs746870898; called by muse, mutect2
- TTI1 | c.3036G>C p.L1012F | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV100989593; called by muse, mutect2
- XIRP1 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs149781655; called by muse, mutect2
- ATP6V1C2 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.129); called by muse, varscan2
- C1QTNF4 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ERICH3 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- FBN1 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 38/562 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2
- KCNA7 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NIPBL | c.4867G>C p.D1623H | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR11H1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 24/636 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2
- POMT2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 47/523 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2
- PRAMEF18 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 20/760 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- PTPRQ | c.2513A>T p.Y838F (on ENST00000616559; = p.Y796F on NM_001145026.2) | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2
- SPINT4 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ZNF521 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS7 | c.222G>A p.V74= | Silent (SNP) | VAF 33/493 reads (7%) | catalogued as rs1186431611; called by muse, mutect2
- CTU2 | c.1533G>A p.E511= | Silent (SNP) | VAF 25/281 reads (9%) | called by muse, mutect2
- DCANP1 | c.387G>T p.R129= | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- IGSF9B | c.4158C>T p.P1386= | Silent (SNP) | VAF 25/306 reads (8%) | called by muse, mutect2
- INTS4 | c.1320C>T p.N440= | Silent (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- KCNA5 | c.642C>T p.R214= | Silent (SNP) | VAF 26/452 reads (6%) | catalogued as COSV99364284; called by muse, mutect2
- KCNK13 | c.744C>T p.N248= | Silent (SNP) | VAF 37/327 reads (11%) | catalogued as rs574638305, COSV56411938; called by muse, mutect2, varscan2
- KIT | c.396G>A p.T132= | Silent (SNP) | VAF 29/298 reads (10%) | catalogued as rs149172424; ClinVar: likely benign; called by muse, mutect2
- OR4C3 | c.336G>A p.L112= | Silent (SNP) | VAF 19/213 reads (9%) | catalogued as rs751701761, COSV60585775; called by muse, mutect2
- PCDHGA10 | c.813C>T p.T271= | Silent (SNP) | VAF 10/291 reads (3%) | catalogued as COSV99536562; called by muse, mutect2
- TMEM45B | c.798C>T p.T266= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as rs748461412; called by muse, mutect2
- UNC79 | c.3939C>T p.Y1313= (on ENST00000393151 / NM_001346218.2; = p.Y1136= on NM_020818.5) | Silent (SNP) | VAF 24/301 reads (8%) | catalogued as rs767249315; called by muse, mutect2
- WNT7A | c.1041G>A p.T347= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs774521816, COSV53197249; called by muse, mutect2
- KCNMA1 | c.2267-4485G>A | Intron (SNP) | VAF 14/220 reads (6%) | catalogued as rs978214921; called by muse, mutect2
- PTENP1 | n.1105C>T | RNA (SNP) | VAF 34/257 reads (13%) | catalogued as rs1416902697; called by muse, mutect2, varscan2
- UNC5A | c.293-2459C>T | Intron (SNP) | VAF 24/179 reads (13%) | catalogued as rs1245342617, COSV56174046; called by muse, mutect2, varscan2
